Somatic mutation profile of tumor specimen BA3176D (aliquot aq-BA3176D) from BEATAML1.0 case 2765, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.1 years (19,377 days).
Specimen BA3176D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daaf39c6-f9bb-4ce2-8243-e1a25ebc0035.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3115D (Solid Tissue Normal), aliquot aq-BA3115D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/493bb521-2b6c-4409-8ba2-64ac66769041

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Frame Shift Ins 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMC1A | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs122454123, CM071098; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM5C | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 142/608 reads (23%) | catalogued as COSV64767473; called by muse, mutect2, varscan2
- PRPF8 | c.4781G>A p.C1594Y | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs770896496, COSV59261386; called by muse, mutect2
- LAMA5 | c.5622C>T p.L1874= | Silent (SNP) | VAF 69/172 reads (40%) | called by muse, mutect2, varscan2
